Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A51W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A51W-01A (Primary Tumor).

[page 1 of 5]
TEST(S):

1 Slide,

ICD- O-3

Carcinoma, Squamous cell, NOS
8070/3

Site: tonsil. NOS CO2.9

FINAL DIAGNOSIS:

Tonsil, left fossa, biopsy

fw
10/25/12

- Invasive squamous cell carcinoma, moderately-differentiated

(keratinizing).

COMMENT:

We agree with the referring pathologist's report and appreciate the opportunity to review this case.

CLINICAL HISTORY:

The patient is a year-old female with newly diagnosed tonsil cancer.

GROSS:

Received one stained slide labeled) and a copy of the referring pathologist's report with patient identifying information. One slide is returned.

MICROSCOPIC:

Microscopic examination is performed.

fw
10/25/12

[page 2 of 5]
SPECIMEN(S):

A: Wide local excision left RMT and tonsillar fossa

B: Left anterior RMT margin

C: Superior buccal margin

D: Maxillary tuberosity

E: Superior medial palatal margin

F: Tongue base

FINAL DIAGNOSIS:

A. Wide local excision left RMT and tonsillar fossa:

- Squamous cell carcinoma, moderately differentiated, invasive.
- Tumor size: 2.0 x 1.8 x 0.7 cm (Maximum depth of invasion: 0.7 cm)
- Margins: All margins free of tumor.
- Closest, deep margin at 0.1 cm from tumor.
- No evidence of vascular or perineural invasion.

B. Left anterior RMT margin:

- No evidence of high-grade dysplasia or malignancy.

C. Superior buccal margin:

- No evidence of high-grade dysplasia or malignancy.

[page 3 of 5]
D. Maxillary tuberosity:

- No evidence of high-grade dysplasia or malignancy.

E. Superior medial palatal margin:

- No evidence of high-grade dysplasia or malignancy.

F. Tongue base:

- No evidence of high-grade dysplasia or malignancy.

COMMENT:

All frozen section diagnoses are confirmed on permanent sections.

CLINICAL HISTORY:

The patient is a year-old female with a history of tonsil cancer.

GROSS:

Received are six containers labeled with the patient's name and medical record number. All tissue was received fresh.

A. The first container is additionally labeled "wide local excision, left retromolar trigone and tonsillar fossa" consists of a 4.0 x 2.7 cm portion of tan-red rubbery mucosa and submucosa tissue which is excised to a depth of 1.2 cm. The surgeon is present in the gross room and

[page 4 of 5]
oriented the specimen. A 2.0 x 1.8 cm ulcerated and ill-defined firm mass is present on the mucosal surface. The specimen is inked as follows: Anterior = blue, superior = green, lateral = red, medial = orange, deep = black. On sectioning, the mass measures up to 0.7 cm in thickness and is less than 0.1 cm from the deep margin. The mass is 0.2 cm to lateral, 1.0 cm to medial, 1.3 cm to anterior, and 0.9 cm to superior margin. Representative tissue was procured for potential future studies from specimen A.

Summary of sections: Representative sections:

A1 - anterior margin, perpendicular.

A2-A4 - mass full thickness with medial and lateral margins. =

A5 - mass with superior margin, perpendicular.

B. The next container is additionally labeled "B - left anterior retromolar trigone margin" and consists of a 0.4 x 0.3 x 0.2 cm tan-pink soft tissue, entirely submitted for frozen section and remnant in B1FS.

C. The next container is additionally labeled "C - superior buccal margin" and contains a 1.1 x 0.4 x 0.3 cm tan-pink soft tissue, entirely submitted for frozen section as remnant C1FS.

D. The next container is additionally labeled "D - maxillary tuberosity" and contains a 0.7 x 0.5 x 0.2 cm tan soft tissue. Entirely submitted for frozen section remnant in D1FS.

[page 5 of 5]
E. The next container is additionally labeled "E - superomedial palatal margin" contains a 0.6 x 0.4 x 0.2 cm tan-pink soft tissue, entirely submitted for frozen section remnant in E1FS.

F. The next container is additionally labeled "F - tongue base" and contains a 1.0 x 0.5 x 0.3 cm tan-red soft tissue, entirely submitted for frozen section remnant in F1FS.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

BFS1: Oral cavity, left anterior right molar trigone margin excision -

"No evidence of malignancy."

CFS1: Oral cavity, superior buccal margin - "No evidence of high grade dysplasia or malignancy."

DFS1: Oral cavity, maxillary tuberosity excision - "No evidence of high grade dysplasia or malignancy."

EFS1: Oral cavity, superomedial palatal margin excision - "No evidence of high grade dysplasia or malignancy."

FFS1: Oropharynx, tongue base, excision - "No evidence of malignancy."

MICROSCOPIC:

Microscopic examination is performed.

Source: NCI Genomic Data Commons file 200a5a4f-4488-4963-8dc9-89155eece26b (TCGA-MT-A51W.051AD90B-1773-48E5-8744-BC61D92D3A14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).